Somatic mutation profile of tumor specimen MP2PRT-PASKAG-TMP1-A (aliquot MP2PRT-PASKAG-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASKAG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,302 days).
Specimen MP2PRT-PASKAG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71548f6f-5c67-4ddf-9444-fedfb7cde3c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKAG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKAG-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/918d3788-3d3b-427c-8707-1814aa0e2dbd

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 2, 3'UTR 1, Intron 1, Frame Shift Ins 1, Nonstop Mutation 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4493G>A p.R1498Q | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1567269945, COSV52132256; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 26/352 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 78/297 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW10 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs910536209; called by mutect2, varscan2
- FTHL17 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 64/974 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV63266778, COSV63267286; called by muse, mutect2
- KATNIP | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs201676999; called by muse, mutect2
- KRTAP15-1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 182/860 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375953985, COSV61877522; called by muse, mutect2, varscan2
- LYPD2 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 50/666 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766170996, COSV63649125; called by muse, mutect2
- MYH2 | c.5386G>A p.V1796M | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs778350338, COSV55432863; called by muse, mutect2, varscan2
- NGFR | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 290/637 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1400123877; called by muse, mutect2, varscan2
- NPAS3 | c.2626G>T p.V876L (on ENST00000356141 / NM_001164749.2; = p.V844L on NM_022123.3) | Missense Mutation (SNP) | VAF 97/649 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV60865424; called by muse, mutect2, varscan2
- PXDNL | c.3319G>A p.V1107M | Missense Mutation (SNP) | VAF 122/547 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs770252979, COSV100683091; called by muse, mutect2, varscan2
- RYR2 | c.4762G>A p.V1588M | Missense Mutation (SNP) | VAF 16/498 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV100768849; called by muse, mutect2
- SH2B3 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 339/501 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs982851788, COSV57981281; called by muse, mutect2, varscan2
- TEKT3 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs771632343, COSV58627145; called by muse, mutect2, varscan2
- TNK2 | c.1482dup p.D495Rfs*25 | Frame Shift Ins (INS) | VAF 16/148 reads (11%) | catalogued as rs750898925; called by mutect2, varscan2
- UTP4 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1482637854, COSV58735387; called by muse, mutect2, varscan2
- ZAR1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 28/994 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV56718985; called by muse, mutect2
- ABCB10 | c.551T>G p.I184S | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- FAT1 | c.8335C>G p.L2779V | Missense Mutation (SNP) | VAF 23/642 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2
- FAT1 | c.3736C>G p.L1246V | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.687); called by muse, mutect2
- IGKV1OR2-108 | chr2:113406869 CATTC>TTT | Missense Mutation (DEL) | VAF 23/134 reads (17%) | called by pindel, varscan2*
- IL9R | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 95/1049 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2
- ITGA9 | c.2690C>A p.S897Y | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- KMT2D | c.14671C>T p.Q4891* | Nonsense Mutation (SNP) | VAF 136/320 reads (43%) | called by muse, mutect2, varscan2
- REX1BD | c.247A>T p.R83* | Nonsense Mutation (SNP) | VAF 135/460 reads (29%) | called by muse, mutect2, varscan2
- SEC61A2 | c.1429T>C p.*477Qext*10 | Nonstop Mutation (SNP) | VAF 10/249 reads (4%) | called by muse, mutect2
- SLC38A5 | c.438C>G p.I146M | Missense Mutation (SNP) | VAF 34/682 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SUZ12 | c.1813G>C p.D605H | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TMEM271 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ZNF219 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 78/718 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF658 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- ZSWIM8 | c.3813G>C p.Q1271H (on ENST00000605216 / NM_001242487.2; = p.Q1276H on NM_015037.3) | Missense Mutation (SNP) | VAF 25/692 reads (4%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.986); called by muse, mutect2
- ANO8 | c.1869C>T p.G623= | Silent (SNP) | VAF 23/744 reads (3%) | catalogued as rs1393907779; called by muse, mutect2
- C5orf49 | c.36G>A p.T12= | Silent (SNP) | VAF 16/520 reads (3%) | called by muse, mutect2
- CALHM6 | c.411C>A p.R137= | Silent (SNP) | VAF 126/589 reads (21%) | called by muse, mutect2, varscan2
- DMD | c.9090C>T p.A3030= | Silent (SNP) | VAF 31/591 reads (5%) | catalogued as CD951683; called by muse, mutect2
- ENTPD4 | c.828G>A p.S276= | Silent (SNP) | VAF 105/447 reads (23%) | catalogued as rs764827906; called by muse, mutect2, varscan2
- FRMD4B | c.468G>A p.L156= | Silent (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- MYOD1 | c.867C>T p.S289= | Silent (SNP) | VAF 52/664 reads (8%) | catalogued as rs1489313064; called by muse, mutect2
- PCDHGB7 | c.1506G>A p.S502= | Silent (SNP) | VAF 48/635 reads (8%) | catalogued as COSV53922315; called by muse, mutect2
- R3HDM2 | c.2574G>A p.L858= | Silent (SNP) | VAF 31/389 reads (8%) | called by muse, mutect2
- ATP13A2 | c.*193G>T | 3'UTR (SNP) | VAF 27/547 reads (5%) | called by muse, mutect2
- FOXP1 | c.181-17987C>G | Intron (SNP) | VAF 15/428 reads (4%) | called by muse, mutect2
- IGHV3-53 | chr14:106592675 ins AGAGCCAGGCCATCCCCCCAGCAACGCA | 3'Flank (INS) | VAF 16/176 reads (9%) | called by mutect2, pindel
- PKD1L2 | n.183G>C | RNA (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
